Somatic mutation profile of tumor specimen TCGA-OR-A5JK-01A (aliquot TCGA-OR-A5JK-01A-11D-A29I-10) from TCGA case TCGA-OR-A5JK, project TCGA-ACC (Adrenocortical Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Cortex of adrenal gland; Age at diagnosis: 49.9 years (18,214 days).
Specimen TCGA-OR-A5JK-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b8a1d422-9a62-488f-b2f2-e71a5d784f7b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-OR-A5JK-10A (Blood Derived Normal), aliquot TCGA-OR-A5JK-10A-01D-A29L-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/56dbacf6-a1e6-4f91-b44c-86fb03c97ff0

The open-access MAF lists 27 somatic variants for this specimen: 21 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 16, Silent 6, Nonsense Mutation 3, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AREG | c.122C>T p.S41F | Missense Mutation (SNP) | VAF 146/1526 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as rs770444196; called by muse, mutect2
- CCAR2 | c.2012C>T p.S671L | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT tolerated (0.29); PolyPhen benign (0.01); catalogued as rs761013874, COSV52386201; called by muse, mutect2, varscan2
- CMYA5 | c.4792G>A p.V1598I | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1205488895; called by muse, mutect2, varscan2
- KLHL42 | c.1219C>T p.R407C | Missense Mutation (SNP) | VAF 68/201 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1190271926, COSV67146293; called by muse, mutect2, varscan2
- RPP38 | c.184G>T p.D62Y | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0.05); PolyPhen benign (0.233); catalogued as rs776711730, COSV65381807; called by muse, mutect2, varscan2
- SYT4 | c.181G>A p.D61N | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.989); catalogued as rs368892366; called by muse, mutect2, varscan2
- BPNT1 | c.519_540del p.L173Ffs*3 | Frame Shift Del (DEL) | VAF 92/155 reads (59%) | called by pindel, varscan2*
- DDX50 | c.650T>A p.L217* | Nonsense Mutation (SNP) | VAF 8/173 reads (5%) | called by muse, mutect2
- ECPAS | c.5258C>A p.A1753D | Missense Mutation (SNP) | VAF 55/97 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- LAMB4 | c.4530C>G p.H1510Q | Missense Mutation (SNP) | VAF 19/223 reads (9%) | SIFT tolerated (0.3); PolyPhen benign (0.105); called by muse, mutect2
- MARS1 | c.2060T>G p.L687R | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYLK2 | c.977T>C p.M326T | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT tolerated (0.53); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- NCOR2 | c.1436A>G p.Y479C | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NLGN4X | c.1231G>T p.E411* | Nonsense Mutation (SNP) | VAF 100/196 reads (51%) | called by muse, mutect2, varscan2
- NLN | c.1812C>G p.C604W | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PGAP1 | c.2627C>G p.S876* | Nonsense Mutation (SNP) | VAF 87/134 reads (65%) | called by muse, mutect2, varscan2
- RARA | c.571_595del p.V191Sfs*71 | Frame Shift Del (DEL) | VAF 11/23 reads (48%) | called by mutect2, pindel, varscan2
- SLC35B3 | c.811T>C p.Y271H | Missense Mutation (SNP) | VAF 77/146 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- STMN2 | c.163G>C p.E55Q | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.588); called by mutect2, varscan2
- TKTL2 | c.408G>A p.M136I | Missense Mutation (SNP) | VAF 50/144 reads (35%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.999); called by muse, varscan2
- TRIP13 | c.947A>G p.K316R | Missense Mutation (SNP) | VAF 62/187 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- BNC2 | c.3294A>T p.V1098= | Silent (SNP) | VAF 65/107 reads (61%) | called by muse, mutect2, varscan2
- KIF17 | c.1851C>T p.A617= | Silent (SNP) | VAF 34/62 reads (55%) | catalogued as rs762833089; called by muse, mutect2, varscan2
- NF1 | c.1329T>C p.F443= | Silent (SNP) | VAF 99/176 reads (56%) | catalogued as CD1212628; called by muse, mutect2, varscan2
- OLFM4 | c.69G>A p.G23= | Silent (SNP) | VAF 30/42 reads (71%) | called by muse, mutect2, varscan2
- RAD17 | c.1035A>T p.S345= (on ENST00000380774 / NM_133339.2; = p.S334= on NM_002873.1) | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as rs140360093; called by muse, mutect2, varscan2
- UTP14A | c.1662G>A p.K554= | Silent (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
